Somatic mutation profile of tumor specimen 0DFO1A from CCDI case PBBSHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,476 days).
Specimen 0DFO1A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d38d27b2-5dd4-4ae1-93c8-6381a0f9c6b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFO15 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/424a0fe0-6476-4f48-915a-4635c3c895ae

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 2, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 356/1018 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- ARHGAP1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 52/818 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs760960194, COSV100358100; ClinVar: likely benign; called by muse, mutect2
- IRAG1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 293/1022 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367713023; called by muse, mutect2, varscan2
- SLC25A10 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 269/760 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1417326381; called by muse, mutect2, varscan2
- ZMYND8 | c.2351C>T p.T784M (on ENST00000311275 / NM_001363741.2; = p.T804M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/932 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs369116353; called by muse, mutect2
- ADD3 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 87/1209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AL662899.2 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 242/504 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ALOX12 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 168/455 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BEND3 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 32/648 reads (5%) | called by muse, mutect2
- CACTIN | c.760C>G p.R254G | Missense Mutation (SNP) | VAF 157/573 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSTL5 | c.1395A>G p.I465M | Missense Mutation (SNP) | VAF 70/1637 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2
- GMFG | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 184/728 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPATCH8 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 175/639 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIN54 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 222/798 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LYST | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 482/1618 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- MTMR1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 52/1216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- SYNCRIP | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 28/1023 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR87 | c.7615G>T p.E2539* | Nonsense Mutation (SNP) | VAF 36/504 reads (7%) | called by muse, mutect2
- ADCY1 | c.1971C>T p.I657= | Silent (SNP) | VAF 176/669 reads (26%) | called by muse, mutect2, varscan2
- EPPK1 | c.2223C>T p.D741= | Silent (SNP) | VAF 11/334 reads (3%) | catalogued as rs1011327325; called by muse, mutect2
- LAMB2 | c.3756C>T p.A1252= | Silent (SNP) | VAF 199/724 reads (27%) | catalogued as rs773560262, COSV100026334; called by muse, mutect2, varscan2
- SLC17A7 | c.1032C>T p.S344= | Silent (SNP) | VAF 114/363 reads (31%) | called by muse, mutect2, varscan2
- MED17 | c.774+43C>A | Intron (SNP) | VAF 201/653 reads (31%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40421323 G>A | 3'Flank (SNP) | VAF 190/677 reads (28%) | catalogued as rs772498406; called by muse, mutect2, varscan2
- PRPF31 | c.421-21A>T | Intron (SNP) | VAF 253/725 reads (35%) | called by muse, mutect2, varscan2
